Somatic mutation profile of tumor specimen TCGA-B9-A8YI-01A (aliquot TCGA-B9-A8YI-01A-21D-A36X-10) from TCGA case TCGA-B9-A8YI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 79.2 years (28,917 days).
Specimen TCGA-B9-A8YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 500d2f44-2161-42f1-a066-7776bae53dde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A8YI-10A (Blood Derived Normal), aliquot TCGA-B9-A8YI-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7089e962-6a66-4ab2-810b-aeca03a22992

The open-access MAF lists 124 somatic variants for this specimen: 97 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 21, Frame Shift Del 12, Nonsense Mutation 4, Splice Site 4, Frame Shift Ins 3, RNA 2, Nonstop Mutation 2, Intron 2, 3'Flank 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 182/469 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7158C>A p.F2386L | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101447032; called by muse, mutect2, varscan2
- ADAM10 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as COSV99546141, COSV99546273; called by muse, mutect2, varscan2
- ADM | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs771306099, COSV99534306; called by muse, mutect2, varscan2
- ANP32D | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56980271, COSV99874355; called by muse, mutect2, varscan2
- ATXN7L1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.259); catalogued as COSV100596924; called by muse, mutect2, varscan2
- BICC1 | c.601-2A>G p.X201_splice | Splice Site (SNP) | VAF 38/88 reads (43%) | catalogued as COSV54065777; called by muse, mutect2, varscan2
- BTBD6 | c.1292C>A p.T431K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100527487, COSV59268138; called by muse, mutect2, varscan2
- CCDC57 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV101051969; called by muse, mutect2, varscan2
- CEP63 | c.681A>G p.I227M | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV100132908; called by muse, mutect2, varscan2
- CGAS | c.1102A>C p.N368H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV100943686; called by muse, mutect2, varscan2
- CHD5 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1034284360, COSV52421178; called by muse, mutect2, varscan2
- CIB1 | c.302C>A p.T101K | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV60173927; called by muse, mutect2, varscan2
- CLDN3 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV101230851; called by muse, mutect2, varscan2
- CNNM4 | c.975C>G p.D325E | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); catalogued as COSV100998745; called by muse, mutect2, varscan2
- COLQ | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV101082396; called by muse, mutect2, varscan2
- COP1 | c.880A>C p.K294Q | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.95); catalogued as COSV100443564; called by muse, mutect2, varscan2
- CRISP2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as rs778468442, COSV100189124; called by muse, mutect2, varscan2
- CSF1R | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642461; called by muse, mutect2, varscan2
- DLGAP3 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV99332890; called by muse, mutect2, varscan2
- DPP7 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV100857388; called by muse, mutect2, varscan2
- ENO1 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52303362, COSV99318890; called by muse, mutect2, varscan2
- ERCC5 | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99958916; called by muse, mutect2, varscan2
- ERP29 | c.233A>C p.E78A | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as COSV99923643; called by muse, mutect2, varscan2
- ETS1 | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as COSV100091019; called by muse, mutect2, varscan2
- FCSK | c.63T>A p.S21R | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99851086; called by muse, mutect2, varscan2
- FHOD1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as rs746053817, COSV99263962; called by muse, mutect2, varscan2
- FNIP2 | c.3175C>G p.L1059V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100033029; called by muse, mutect2, varscan2
- FREM2 | c.7756T>C p.Y2586H | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV99749612; called by muse, mutect2, varscan2
- GABRB2 | c.677C>A p.T226K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99196307; called by muse, mutect2
- GAD2 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV99393596; called by muse, mutect2, varscan2
- GEMIN4 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021363; called by muse, mutect2
- GPR87 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV99608878; called by muse, mutect2, varscan2
- HOXA10 | c.1055A>G p.E352G | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385562; called by muse, mutect2, varscan2
- IGF2R | c.1813T>A p.C605S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100807717; called by muse, mutect2, varscan2
- ILVBL | c.893del p.P298Qfs*28 | Frame Shift Del (DEL) | VAF 71/233 reads (30%) | catalogued as COSV99655091; called by mutect2, pindel, varscan2
- ITGA2B | c.1713G>T p.K571N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV99289035; called by muse, mutect2, varscan2
- ITGB8 | c.430A>C p.K144Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99751850; called by muse, mutect2, varscan2
- IVNS1ABP | c.532-1G>T p.X178_splice | Splice Site (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100832509, COSV100832543; called by muse, mutect2, varscan2
- JADE3 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510031; called by muse, mutect2, varscan2
- KAT7 | c.787A>C p.K263Q | Missense Mutation (SNP) | VAF 208/475 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99371935; called by muse, mutect2, varscan2
- KLF3 | c.290T>C p.M97T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99789838; called by muse, mutect2, varscan2
- KLHL1 | c.1494G>C p.Q498H | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100917671; called by muse, mutect2, varscan2
- KMT2C | c.8422G>A p.D2808N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV100073988; called by muse, mutect2, varscan2
- KRT9 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.604); catalogued as COSV99879274; called by muse, mutect2, varscan2
- MACO1 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.969); catalogued as COSV100975214; called by muse, mutect2, varscan2
- MCM6 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202222981, COSV99919226; called by muse, mutect2, varscan2
- MKI67 | c.2240A>T p.D747V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100896766; called by muse, mutect2, varscan2
- MUC6 | c.3650C>A p.P1217H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV101424672; called by muse, mutect2, varscan2
- NFKB2 | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV99192992; called by muse, mutect2, varscan2
- NINJ2 | c.363C>A p.F121L | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99843268; called by muse, mutect2, varscan2
- NSG1 | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1001392519, COSV101207952; called by muse, mutect2, varscan2
- NUP210 | c.3228+2T>C p.X1076_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99596552; called by mutect2, varscan2
- OR11L1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563634223, COSV100869450; called by muse, mutect2, varscan2
- OR56A3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100290311, COSV61568779; called by muse, mutect2, varscan2
- PAH | c.629T>A p.F210Y | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100188232; called by muse, mutect2, varscan2
- PARD6B | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100859988; called by muse, mutect2, varscan2
- PCCA | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.323); catalogued as COSV100886984; called by muse, mutect2, varscan2
- PCK1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755746992, COSV100100660; called by muse, mutect2, varscan2
- PNPLA7 | c.3901C>A p.P1301T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV99481060; called by muse, mutect2, varscan2
- PRDM11 | c.301A>C p.S101R (on ENST00000530656 / NM_001359633.1; = p.S67R on NM_001256695.1) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99770923; called by muse, mutect2, varscan2
- PTPRU | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100113206, COSV60521249, COSV60528613; called by muse, mutect2, varscan2
- PURA | c.875G>A p.C292Y | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV100495757; called by muse, mutect2, varscan2
- RAB21 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99714906; called by muse, mutect2, varscan2
- RAD50 | c.3545A>C p.Y1182S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54747040, COSV99529204; called by muse, mutect2, varscan2
- RGS14 | c.1699T>C p.*567Rext*163 | Nonstop Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101281731; called by muse, mutect2, varscan2
- SCO1 | c.507C>G p.C169W | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99703573; called by muse, mutect2, varscan2
- SGK1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV99398596; called by muse, mutect2, varscan2
- SPRY1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV100201867; called by muse, mutect2, varscan2
- SSH1 | c.215-2A>T p.X72_splice | Splice Site (SNP) | VAF 80/177 reads (45%) | catalogued as rs1344212013, COSV100425663; called by muse, mutect2, varscan2
- ST8SIA5 | c.748T>G p.Y250D | Missense Mutation (SNP) | VAF 47/90 reads (52%) | PolyPhen probably damaging (0.995); catalogued as COSV100164807; called by muse, mutect2, varscan2
- STMN1 | c.174A>T p.E58D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100771316; called by muse, mutect2, varscan2
- SUDS3 | c.987A>C p.*329Cext*8 | Nonstop Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV64348765; called by muse, mutect2, varscan2
- SYNE1 | c.24187T>C p.Y8063H (on ENST00000367255 / NM_182961.4; = p.Y7992H on NM_033071.3) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571178; called by muse, mutect2, varscan2
- TBC1D22A | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100453415; called by muse, mutect2, varscan2
- TLR2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV52604813; called by muse, mutect2, varscan2
- UBL4A | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs782123473, COSV99682163; called by muse, mutect2, varscan2
- USP28 | c.1961A>T p.Y654F | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99135876; called by muse, mutect2, varscan2
- VPS18 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV99592572; called by muse, mutect2, varscan2
- WDFY3 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV99884404; called by muse, mutect2, varscan2
- ZNF804B | c.1965C>G p.N655K | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100304684; called by muse, mutect2, varscan2
- B4GALNT2 | c.411_412del p.N137Kfs*5 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- B4GALT1 | c.17_25delinsGC p.P6Rfs*40 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | called by pindel, varscan2*
- CDH1 | c.2477del p.P826Lfs*20 | Frame Shift Del (DEL) | VAF 40/167 reads (24%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.955del p.L319Cfs*40 | Frame Shift Del (DEL) | VAF 43/141 reads (30%) | called by mutect2, pindel, varscan2
- CUL3 | c.1830del p.K610Nfs*44 | Frame Shift Del (DEL) | VAF 40/117 reads (34%) | called by mutect2, pindel, varscan2
- FKBP5 | c.215_240del p.D72Afs*41 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- IARS2 | c.2690del p.N897Mfs*10 | Frame Shift Del (DEL) | VAF 36/149 reads (24%) | called by mutect2, pindel, varscan2
- NAA15 | c.1917del p.E640Kfs*22 | Frame Shift Del (DEL) | VAF 219/606 reads (36%) | called by mutect2, varscan2
- NCKAP1L | c.3085A>T p.N1029Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- PTPN14 | c.796_802del p.T266* | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- SCAF11 | c.975dup p.N326* | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- SCN8A | c.5886_5891del p.E1963_G1964del | In Frame Del (DEL) | VAF 119/351 reads (34%) | called by mutect2, pindel, varscan2
- SHPRH | c.4685dup p.T1563Dfs*10 (on ENST00000275233 / NM_001042683.3; = p.T1567Dfs*10 on NM_173082.3) | Frame Shift Ins (INS) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- SYTL2 | c.2122del p.I708Sfs*2 (on ENST00000528231 / NM_001162951.2; = p.I684Sfs*2 on NM_032943.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | called by mutect2, pindel, varscan2
- UGT3A2 | c.395_396del p.D132Vfs*5 | Frame Shift Del (DEL) | VAF 58/147 reads (39%) | called by mutect2, varscan2
- WAC | c.1877_1880dup p.F628Tfs*8 | Frame Shift Ins (INS) | VAF 60/218 reads (28%) | called by mutect2, pindel, varscan2
- ABCC6 | c.4386C>G p.S1462= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as COSV99229134; called by muse, mutect2, varscan2
- ABHD13 | c.528G>A p.V176= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV101024209; called by muse, mutect2, varscan2
- CENPT | c.1512T>C p.H504= | Silent (SNP) | VAF 35/190 reads (18%) | catalogued as COSV99535233; called by muse, mutect2, varscan2
- CEP152 | c.343C>A p.R115= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV100358962; called by muse, mutect2, varscan2
- CTNNB1 | c.1578T>G p.P526= | Silent (SNP) | VAF 59/148 reads (40%) | catalogued as COSV100846300; called by muse, mutect2, varscan2
- DIS3L2 | c.909C>T p.C303= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs933918889, COSV99806747; called by muse, mutect2, varscan2
- GPRIN1 | c.1374G>A p.P458= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs537978021, COSV56141904; called by muse, mutect2, varscan2
- HERC1 | c.4654T>C p.L1552= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as COSV101496714; called by muse, mutect2, varscan2
- KLHL20 | c.1806A>G p.T602= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99268522; called by muse, mutect2, varscan2
- MKI67 | c.2241C>T p.D747= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100896765; called by muse, mutect2, varscan2
- NRP1 | c.1662T>C p.F554= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99589186; called by muse, mutect2
- NT5C3B | c.786G>A p.E262= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV99505258; called by muse, mutect2, varscan2
- PIGG | c.1228A>C p.R410= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV99574087; called by muse, mutect2, varscan2
- RAB21 | c.672T>C p.S224= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as rs759825329, COSV99714903; called by muse, mutect2, varscan2
- RRP8 | c.531T>G p.P177= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- SASH1 | c.2049C>T p.H683= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1015782282, COSV100821296; called by muse, mutect2, varscan2
- SCRN2 | c.417G>T p.L139= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV99274189; called by muse, mutect2, varscan2
- TMEM150C | c.159A>C p.P53= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as COSV101496936; called by muse, mutect2, varscan2
- TNKS | c.1377T>C p.A459= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV100127420; called by muse, mutect2, varscan2
- UBTD1 | c.474C>A p.G158= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100080957; called by muse, mutect2, varscan2
- WASF2 | c.459T>G p.P153= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV101420805; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701138 G>A | 3'Flank (SNP) | VAF 54/136 reads (40%) | catalogued as rs1411854955; called by muse, mutect2, varscan2
- MIR200A | n.77C>T | RNA (SNP) | VAF 82/197 reads (42%) | called by muse, mutect2, varscan2
- MIR573 | n.68T>G | RNA (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
- NCOA7 | c.2096+9187del | Intron (DEL) | VAF 28/107 reads (26%) | called by mutect2, pindel, varscan2
- NUFIP1 | c.*1G>C | 3'UTR (SNP) | VAF 61/147 reads (41%) | catalogued as COSV100998030; called by muse, mutect2, varscan2
- TCP1 | c.1098-167C>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100364979; called by muse, mutect2
